Gene-level copy-number profile of tumor specimen C3L-05815-60 from CPTAC case C3L-05815, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 19.4 years (7,079 days).
Specimen C3L-05815-60: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df109127-d5a1-40c6-a784-c80137d50cad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05815-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,871 have no estimate.
https://portal.gdc.cancer.gov/files/8a9c6963-9343-4f9f-8dd1-cb6a32e0d10a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 5,601; copy number 2: 53,133.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr11:32,052,843–32,085,712, 4 genes (within-gene range 0–1): AL035078.3, AL035078.2, U3, EIF4A2P5.
- chr11:32,097,143–32,343,409, 3 genes (within-gene range 0–1): AL078612.1, THEM7P, AL078612.2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–1): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
